Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48P, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48P-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

....

Clinical Diagnosis & History:
Abdominal mass, sarcoma.

Specimens Submitted:

1: Atypical smooth muscle tumor of left retro-peritoneum

DIAGNOSIS:

1. Left retroperitoneum, resection:
- High grade leiomyosarcoma.
- Tumor size: 4.2 x 3.8 x 2.5 cm.
- Tumor appears completely excised, with narrow margins (< 0.1 cm from the inked undesignated margins).
- Two benign lymph nodes (0/2).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh labeled, "atypical smooth muscle tumor of left retroperitoneum", and consists of one round to oval nodular fragment of red tan firm tissue measuring 4.3 x 3.8 x 2.5 cm. The specimen is un-oriented and is inked black. Cut section reveals a well demarcated tan-yellow rubbery whorled nodule that measures 4.2 x 3.8 x 2.5 cm in greatest dimension and abuts all inked margins. There are two possible lymph nodes identified adjacent to the mass that measure up to 0.3 cm in greatest dimension. The specimen is submitted representatively. TPS is submitted.

Summary of sections:

U-- undesignated
LN possible lymph nodes

** Continued on next page **

ICD-O-3

leiomyosarcoma, NOS
8890/3

Site: Retroperitoneum

9-11-12
R0

C48.0

[page 2 of 2]
[REDACTED]

[REDACTED]

----- Page 2 of 2

Summary of Sections:

Part 1: Atypical smooth muscle tumor of left retro-peritoneum

Block	Sect.	Site	PCs
1		ln	1
5		u	5

** End of Report **

HIV-1A Discrepancy		

12/5/12

Source: NCI Genomic Data Commons file 05dae58e-a3e6-4f8d-8798-c380daffacd9 (TCGA-DX-A48P.BA6335B6-A1D5-4C06-8A6D-000BF9AE3D55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).